Surgical pathology report (de-identified scan), TCGA case TCGA-3A-A9IR, project TCGA-PAAD (Pancreatic Adenocarcinoma), tissue source site Moffitt Cancer Center, specimen TCGA-3A-A9IR-01A (Primary Tumor).

[page 1 of 2]
Pathology Report

Final Diagnosis

A. PANCREAS, DISTAL, AND SPLEEN, PARTIAL PANCREATECTOMY AND SPLENECTOMY:
Well-differentiated pancreatic endocrine tumor.
(See key pathological findings.)
Spleen with no significant pathologic changes.

I, _____ the attending pathologist, personally reviewed all slides and / or materials and rendered the final diagnosis. Electronically Signed Out by _____

Comment

There is no tumor necrosis, the mitotic rate is <2 mitoses/10 high power fields, and the ki-67 immunostain shows positivity in approximately 2% of the tumor cells. The tumor is positive for low molecular weight cytokeratin (CAM 5.2) and glucagon, and it is negative for insulin, by immunohistochemistry. The stains were performed on block A4 with appropriate controls.

Key Pathological Findings

Procedure type: Partial pancreatectomy, pancreatic tail
Tumor site: Pancreatic tail
Tumor focality: Unifocal
Histologic type: Well-differentiated endocrine tumor
Tumor size: 4 x 3.5 x 3.5 cm
Venous/Lymphatic vessel invasion: Present
Perineural invasion: Not identified
Mitotic activity: Less than 2 mitoses/10 high-power field
Ki-67: Approximately 2%
Tumor necrosis: Not identified
Tumor extension: Confined to the pancreas
Margins: Anterior aspect: the tumor is present at < 1 mm from ink
Retroperitoneal aspect: The tumor is present at < 1mm from ink
Stapled pancreatic resection margin: negative of tumor
Regional lymph nodes: 13 lymph nodes, negative for tumor
Additional pathologic findings: Multiple foci of PanIN 1A with a focus of PanIN-2.
Pathologic stage: T2N0MX

Specimen(s) Received

A DISTAL PANCREAS AND SPLEEN 2FS

ICD O-3

Neuroendocrine carcinoma, NOS 8246/3

Site: Pancreas tail C25.2

JP 2/16/14

[page 2 of 2]
Clinical History

PANCREAS MASS / MET PANCREAS

Pancreas mass.

Preoperative Diagnosis

Neuroendocrine tumor, pancreas.

Intraoperative Consultation

FSA1-FSA2. DISTAL PANCREAS AND SPLEEN:

Parenchymal resection margin is negative for carcinoma.

Low-grade PanIN present.

Comment: This frozen section diagnosis/result was communicated to and acknowledged by Dr.

I, _____ M.D., have performed the intraoperative consultation and issued the above diagnosis.

Gross Description

A. The specimen is received fresh labeled "distal pancreas and spleen, stitch=retroperitoneal margin, frozen section=unstapled line". The specimen consists of a distal portion of pancreas (6.5 x 4.6 x 3.5 cm) with attached spleen (9.6 x 6 x 3.5 cm, weight 87.7 g). The portion of distal pancreas is enlarged and distorted by the tumor, which measures up to 4 x 3.5 x 3.5 cm. The tumor is roughly ovoid, well-defined, and is bulging but does not appear to extend through the peritoneum of the anterior aspect of the pancreas. The tumor is 1.0 cm from the stapled, proximal resection margin. The portion of parenchyma located proximal to the tumor is grossly unremarkable. The cut surface of the tumor is variegated, pink-tan to red, focally hemorrhagic. Tangential section of the stapled resection margin is submitted entirely for frozen section as FSA1 and FSA2. Several potential lymph nodes are grossly identified within adipose tissue adjacent to the tail of pancreas. Prior to sectioning, the specimen is inked as follows:

Anterior aspect of the pancreas	Green
Retroperitoneal aspect	Orange

The capsule of the spleen is red-purple, smooth and glistening. On sectioning, the spleen reveals a grossly unremarkable cut surface. Representative sections of the specimen are submitted to Tissue Procurement Laboratory. Additional sections of the specimen are submitted in 19 cassettes A3-A21 as follows:

A3	Mirror image of the section submitted to the Tissue Procurement Laboratory
A4-A6	Tumor bulging peritoneum of the anterior aspect
A7-A13	Tumor in relation to the retroperitoneal resection margin, perpendicular
section	
A14-A17	Additional adipose tissue attached to the tail of pancreas with potential lymph
nodes	
A16-A18	Additional sections of the tumor
A19-A20	Spleen
A21	Hilar adipose tissue with potential lymph nodes.

Source: NCI Genomic Data Commons file 9d5724b5-dc51-4f9d-a9e1-5dab16314006 (TCGA-3A-A9IR.10A8287B-4A3C-4A13-B4D9-8E3894008ACF.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).